Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A029, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A029-01A (Primary Tumor).

TCGA #:	Internal Sample ID
---------	--------------------

Diagnosis:

This involves an invasive, poorly differentiated colon adenocarcinoma (G 3; partially mucinous carcinoma) with penetration of all parietal layers (p T 3), as well as free lymph nodes and free resection margins.

ICD-O-3
adenocarcinoma NOS 8140/3
Site: Cecum (p w CACF) C18.0 hu
3/30/14

IIA Discrepancy		☒

Source: NCI Genomic Data Commons file 1f62935d-4794-418a-9de1-74c809222cdb (TCGA-AA-A029.132B76AD-5B42-4315-B96D-BD4D6BB1F33C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).